Somatic mutation profile of tumor specimen TCGA-78-7159-01A (aliquot TCGA-78-7159-01A-11D-2036-08) from TCGA case TCGA-78-7159, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 60.9 years (22,261 days).
Specimen TCGA-78-7159-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ad830a1-e586-4423-adeb-859a09225081.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-78-7159-10A (Blood Derived Normal), aliquot TCGA-78-7159-10A-01D-2036-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f6ef881-200b-4bc4-960c-fce2a6609da2

The open-access MAF lists 329 somatic variants for this specimen: 244 protein-altering or splice-affecting, 78 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 202, Silent 78, Nonsense Mutation 16, Frame Shift Del 11, Splice Site 6, Frame Shift Ins 4, Splice Region 3, RNA 3, 3'UTR 2, In Frame Del 2, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DMD | c.2257G>T p.E753* | Nonsense Mutation (SNP) | VAF 6/33 reads (18%) | catalogued as rs1557396632, CM159873, COSV55902813, COSV55906108; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC11 | c.1032A>T p.E344D | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62326335; called by muse, mutect2
- ABCC11 | c.1030G>T p.E344* | Nonsense Mutation (SNP) | VAF 6/74 reads (8%) | catalogued as COSV62326338; called by muse, mutect2
- ACADM | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57714759; called by mutect2, varscan2
- ACAN | c.4687G>C p.G1563R | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT tolerated (0.4); PolyPhen probably damaging (1); catalogued as rs771449137, COSV61370968; called by muse, mutect2, varscan2
- ACAP2 | c.1246G>T p.D416Y | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58756687; called by muse, mutect2, varscan2
- ACP7 | c.1078C>A p.P360T | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as COSV58701127; called by muse, mutect2, varscan2
- ACSM3 | c.47T>C p.F16S | Missense Mutation (SNP) | VAF 88/141 reads (62%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as COSV56847352; called by muse, mutect2, varscan2
- ACVR1C | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54650588; called by muse, mutect2, varscan2
- ADAMTS20 | c.1758T>A p.P586= | Splice Region (SNP) | VAF 3/14 reads (21%) | catalogued as COSV67140947; called by muse, mutect2
- ADAMTSL5 | c.1076G>T p.R359L | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV100389271, COSV57861659; called by muse, mutect2, varscan2
- ADCY8 | c.1489C>G p.R497G | Missense Mutation (SNP) | VAF 65/109 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53931562, COSV99653230; called by muse, mutect2, varscan2
- AEBP1 | c.387G>T p.K129N | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.521); catalogued as COSV56261808; called by muse, mutect2, varscan2
- AFDN | c.618G>T p.M206I | Missense Mutation (SNP) | VAF 50/191 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as COSV60059131; called by muse, mutect2, varscan2
- ALOXE3 | c.546G>T p.Q182H | Missense Mutation (SNP) | VAF 72/225 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.332); catalogued as COSV59078418; called by muse, mutect2, varscan2
- ALPI | c.1049C>T p.A350V | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.532); catalogued as rs937976449, COSV55014612; called by muse, mutect2, varscan2
- ANK2 | c.587T>A p.L196Q | Missense Mutation (SNP) | VAF 88/179 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52193163; called by muse, mutect2, varscan2
- ANK3 | c.10550A>T p.D3517V | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.676); catalogued as COSV55076722; called by muse, mutect2, varscan2
- ANO1 | c.2749A>G p.K917E | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV62451137; called by muse, mutect2, varscan2
- API5 | c.113G>A p.G38D | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.921); catalogued as rs35999189; called by muse, mutect2, varscan2
- ARX | c.951C>A p.S317R | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.157); catalogued as COSV66875915; called by muse, mutect2, varscan2
- ASPDH | c.718T>A p.F240I (on ENST00000389208 / NM_001114598.2; = p.F135I on NM_001024656.3) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as COSV65350948; called by muse, mutect2, varscan2
- ASPHD1 | c.592G>T p.A198S | Missense Mutation (SNP) | VAF 68/140 reads (49%) | SIFT tolerated (0.37); PolyPhen benign (0.068); catalogued as COSV58105066; called by muse, mutect2, varscan2
- ASPM | c.9262G>A p.A3088T | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV54140486; called by muse, mutect2, varscan2
- ASTN1 | c.2788C>A p.R930S | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV62508778; called by muse, mutect2, varscan2
- ATRNL1 | c.1002A>C p.L334= | Splice Region (SNP) | VAF 36/111 reads (32%) | catalogued as COSV61818946; called by muse, mutect2, varscan2
- ATRX | c.2128A>G p.N710D | Missense Mutation (SNP) | VAF 10/284 reads (4%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.057); catalogued as COSV64885153; called by muse, mutect2
- AVEN | c.430C>A p.L144I | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV60737888; called by muse, mutect2, varscan2
- B4GALT6 | c.1068G>T p.R356S | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV52705407; called by muse, mutect2, varscan2
- BEST3 | c.1379C>A p.P460H | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV58306691; called by muse, mutect2, varscan2
- BICD1 | c.1164G>T p.K388N | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.037); catalogued as COSV55689571; called by muse, mutect2, varscan2
- BMP5 | c.1135G>T p.A379S | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63707164; called by muse, mutect2
- BNC1 | c.1520T>A p.I507K | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV61759391; called by muse, mutect2, varscan2
- BTG4 | c.253C>A p.H85N | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.259); catalogued as COSV63637175; called by muse, mutect2, varscan2
- C12orf40 | c.1928C>A p.T643N | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61138442; called by muse, mutect2, varscan2
- CACNA1S | c.1622A>T p.Y541F | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV62944647; called by muse, mutect2
- CALB2 | c.700-1G>T p.X234_splice | Splice Site (SNP) | VAF 75/250 reads (30%) | catalogued as COSV100226460, COSV56942834; called by muse, mutect2, varscan2
- CALB2 | c.700G>T p.E234* | Nonsense Mutation (SNP) | VAF 75/249 reads (30%) | catalogued as COSV100226461, COSV56940629; called by muse, mutect2, varscan2
- CDH12 | c.691G>T p.E231* | Nonsense Mutation (SNP) | VAF 30/73 reads (41%) | catalogued as COSV66454712; called by muse, mutect2, varscan2
- CDH19 | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.314); catalogued as COSV50960400; called by muse, mutect2, varscan2
- CELSR1 | c.8160G>T p.K2720N | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.321); catalogued as COSV53101525; called by muse, mutect2, varscan2
- CEP128 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.313); catalogued as COSV53679068, COSV53679196; called by muse, mutect2, varscan2
- CEP192 | c.3922G>T p.V1308L | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.275); catalogued as COSV58070165, COSV58071610; called by muse, mutect2, varscan2
- CHL1 | c.1955A>T p.N652I (on ENST00000397491 / NM_001253387.1; = p.N668I on NM_006614.4) | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV56608883; called by muse, mutect2, varscan2
- COL19A1 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV59578855; called by muse, mutect2, varscan2
- COL6A6 | c.2743C>A p.L915I | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV62039659; called by muse, mutect2, varscan2
- CPD | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147588955; called by muse, mutect2
- CPNE7 | c.400G>T p.V134F | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs760485243, COSV52017024; called by muse, mutect2, varscan2
- CYP26B1 | c.745A>T p.K249* | Nonsense Mutation (SNP) | VAF 13/72 reads (18%) | catalogued as COSV50015334; called by muse, mutect2, varscan2
- CYP8B1 | c.175C>A p.R59S | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.863); catalogued as COSV100296333; called by muse, mutect2, varscan2
- CYRIA | c.665G>C p.C222S | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV62867543; called by muse, mutect2, varscan2
- DDX11 | c.758A>T p.K253M | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV52512306; called by muse, mutect2, varscan2
- DENND1B | c.1276C>A p.Q426K | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV52473622; called by muse, mutect2, varscan2
- DISP2 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs775657161, COSV51147270; called by muse, mutect2, varscan2
- DMBX1 | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 22/54 reads (41%) | catalogued as COSV63602674; called by muse, mutect2, varscan2
- DMXL1 | c.341A>G p.H114R | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs565699405, COSV60722555; called by muse, mutect2, varscan2
- DNAH9 | c.7111G>C p.E2371Q | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52343834, COSV52380747; called by muse, mutect2, varscan2
- ELF4 | c.1955C>A p.P652H | Missense Mutation (SNP) | VAF 30/223 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV57455590; called by muse, mutect2, varscan2
- EML5 | c.829A>G p.T277A | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV61352576; called by muse, mutect2
- ENTPD1 | c.1500C>A p.H500Q | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.057); catalogued as COSV64604846; called by muse, mutect2, varscan2
- EPHA6 | c.1735C>A p.H579N | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as COSV67596601; called by muse, mutect2, varscan2
- EYS | c.1125G>C p.E375D | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as COSV61001977; called by muse, mutect2, varscan2
- FAM160A2 | c.2205G>C p.Q735H (on ENST00000449352 / NM_001098794.2; = p.Q749H on NM_032127.4) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.969); catalogued as rs768573102, COSV56415354; called by muse, mutect2, varscan2
- FAM234B | c.276G>T p.Q92H | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as COSV52194496; called by muse, mutect2, varscan2
- FAT2 | c.4660C>A p.R1554S | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV55831366; called by muse, mutect2, varscan2
- FAT2 | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV55831375; called by muse, mutect2, varscan2
- FBXL4 | c.194A>T p.Y65F | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100014401; called by muse, varscan2
- FBXL4 | c.193T>A p.Y65N | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57748962; called by muse, varscan2
- FER1L6 | c.5214G>C p.E1738D | Missense Mutation (SNP) | VAF 144/260 reads (55%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as COSV67553259; called by muse, mutect2, varscan2
- FLNA | c.1526G>T p.G509V | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV61053132; called by muse, mutect2, varscan2
- FRMPD1 | c.4488C>G p.H1496Q | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.133); catalogued as COSV66703708; called by muse, mutect2, varscan2
- G6PC | c.776C>A p.A259D | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53833177; called by muse, mutect2, varscan2
- GDF1 | c.-313+3G>A | Splice Region (SNP) | VAF 7/20 reads (35%) | catalogued as rs942847549, COSV55930963; called by muse, mutect2, varscan2
- GIPC1 | c.547G>T p.G183W | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61775179; called by muse, mutect2, varscan2
- GOLGA4 | c.1479G>C p.E493D | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as rs1209171773, COSV62714369; called by muse, mutect2, varscan2
- GOLGA6B | c.1034T>A p.M345K | Missense Mutation (SNP) | VAF 97/264 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV69770677; called by muse, mutect2, varscan2
- GPATCH2 | c.1440G>T p.W480C | Missense Mutation (SNP) | VAF 64/155 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65134753; called by muse, mutect2, varscan2
- GPC6 | c.725C>A p.P242Q | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.223); catalogued as COSV65541538; called by muse, mutect2, varscan2
- GPM6A | c.260G>T p.G87V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54551725, COSV99705887; called by muse, mutect2, varscan2
- GPM6A | c.259G>C p.G87R | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99703000, COSV99705891; called by muse, mutect2, varscan2
- GPR141 | c.256C>A p.P86T | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.033); catalogued as COSV100550502; called by muse, mutect2, varscan2
- GPR141 | c.257C>A p.P86H | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.748); catalogued as COSV100550507; called by muse, mutect2, varscan2
- GPRC5C | c.430G>T p.G144C (on ENST00000652232; = p.G99C on NM_018653.4) | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100703039; called by muse, mutect2, varscan2
- GPRC5C | c.431G>T p.G144V (on ENST00000652232; = p.G99V on NM_018653.4) | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100703045; called by muse, mutect2, varscan2
- GRM7 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63175730; called by mutect2, varscan2
- GUCY2F | c.1309C>A p.P437T | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV54299259; called by muse, mutect2, varscan2
- HHIPL1 | c.1573G>T p.G525C | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58093626, COSV58094031; called by muse, varscan2
- HPN | c.721G>T p.G241W | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52882538, COSV52886631; called by muse, mutect2, varscan2
- IL7R | c.511C>A p.Q171K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as COSV57412122; called by muse, mutect2, varscan2
- INTS6L | c.508G>T p.A170S | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0.402); catalogued as COSV100878001, COSV66086702; called by muse, mutect2, varscan2
- IRAK4 | c.38G>T p.C13F | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1163230363, COSV71211065; called by muse, mutect2, varscan2
- JAG1 | c.2550C>G p.H850Q | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV54763792; called by mutect2, varscan2
- JMJD1C | c.5452A>T p.T1818S | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.243); catalogued as COSV59518271; called by muse, mutect2, varscan2
- KCNH6 | c.1504C>A p.L502M | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV59008346; called by muse, mutect2
- KCNQ5 | c.2326A>T p.S776C | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.43); catalogued as COSV59686049; called by muse, mutect2, varscan2
- KLHL1 | c.394G>A p.G132S | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as rs1443767162, COSV100918186, COSV64786221; called by muse, mutect2, varscan2
- KRT31 | c.193G>C p.D65H | Missense Mutation (SNP) | VAF 44/159 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV52439100; called by muse, mutect2, varscan2
- KRT40 | c.550C>A p.L184I | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV66697231; called by muse, mutect2, varscan2
- KRT6B | c.86G>T p.S29I | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV52887026; called by muse, varscan2
- KRTAP1-5 | c.196T>A p.C66S | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.157); catalogued as COSV62624632; called by muse, mutect2, varscan2
- KRTAP12-2 | c.326G>A p.S109N | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.84); catalogued as COSV59982640; called by muse, mutect2, varscan2
- LAMB1 | c.231C>A p.F77L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55967614; called by muse, mutect2, varscan2
- LCE2D | c.329G>A p.C110Y | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV64229316; called by muse, mutect2, varscan2
- LPA | c.5931G>T p.E1977D | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.283); catalogued as COSV60314380; called by muse, mutect2, varscan2
- LRP1B | c.10670A>T p.Q3557L | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67281806; called by muse, mutect2, varscan2
- LTBP1 | c.2704G>A p.E902K (on ENST00000404816 / NM_206943.4; = p.E576K on NM_000627.4) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as rs755917287, COSV63197620; called by muse, mutect2, varscan2
- MAGEB10 | c.782A>T p.Q261L | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV63312937; called by mutect2, varscan2
- MCC | c.1107G>C p.Q369H | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.644); catalogued as COSV56737544; called by muse, mutect2, varscan2
- MIGA1 | c.478A>T p.K160* | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | catalogued as COSV66225195; called by muse, mutect2, varscan2
- MMP16 | c.382C>A p.Q128K | Missense Mutation (SNP) | VAF 40/246 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV54192832; called by muse, mutect2, varscan2
- MTCL1 | c.2731A>T p.S911C (on ENST00000306329 / NM_001378206.1; = p.S551C on NM_015210.4) | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60412908; called by muse, mutect2, varscan2
- MYH1 | c.4225G>T p.E1409* | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | catalogued as rs752892297, COSV56858494; called by muse, mutect2, varscan2
- MYH10 | c.845A>G p.H282R | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52613199; called by muse, mutect2, varscan2
- MYL10 | c.304G>A p.G102S | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56209317; called by muse, mutect2, varscan2
- MYO7A | c.2863G>T p.G955C | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as CM971016, COSV101289000; called by muse, mutect2, varscan2
- MYO7A | c.2864G>T p.G955V | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV101289316; called by muse, mutect2, varscan2
- MYO7A | c.6493A>G p.T2165A | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60023732; called by muse, mutect2, varscan2
- MYT1L | c.1778C>G p.S593C | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as COSV101221557; called by muse, mutect2, varscan2
- NALCN | c.3947G>C p.G1316A | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV51962998, COSV99218322; called by muse, mutect2, varscan2
- NALCN | c.3946G>T p.G1316* | Nonsense Mutation (SNP) | VAF 31/69 reads (45%) | catalogued as COSV99218330; called by muse, mutect2, varscan2
- NAV1 | c.1363G>A p.V455M | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.041); catalogued as COSV55227717; called by muse, mutect2, varscan2
- NEBL | c.1851T>G p.N617K | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV65806368; called by muse, mutect2
- NEK10 | c.1576G>T p.G526* | Nonsense Mutation (SNP) | VAF 19/40 reads (48%) | catalogued as COSV58290342; called by muse, mutect2, varscan2
- NEURL4 | c.3890G>C p.G1297A | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV59753748; called by muse, mutect2, varscan2
- NKAP | c.1232G>T p.G411V | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57631489; called by muse, mutect2, varscan2
- NLRP14 | c.1802G>A p.C601Y | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55072995; called by muse, mutect2, varscan2
- NME7 | c.160A>T p.N54Y | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as rs1237364474, COSV63171382; called by muse, mutect2, varscan2
- NPHS2 | c.835G>T p.A279S | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.888); catalogued as COSV100858220; called by muse, mutect2, varscan2
- NRROS | c.616G>C p.E206Q | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV60744734, COSV60748124; called by muse, mutect2, varscan2
- NRXN1 | c.2538C>A p.N846K | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58437819, COSV58499742; called by muse, mutect2, varscan2
- NTM | c.550G>T p.E184* | Nonsense Mutation (SNP) | VAF 10/69 reads (14%) | catalogued as COSV66174984, COSV66182780; called by muse, mutect2, varscan2
- NWD1 | c.2669G>A p.G890D | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as COSV60353416; called by muse, mutect2, varscan2
- OR10J5 | c.286G>A p.G96S | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV58387953; called by muse, mutect2, varscan2
- OR2L13 | c.538G>T p.V180F | Missense Mutation (SNP) | VAF 63/199 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV63562727, COSV63563556; called by muse, mutect2, varscan2
- OR2T1 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.304); catalogued as COSV63542936; called by muse, mutect2, varscan2
- OR2T4 | c.105G>T p.M35I | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV63545264; called by muse, mutect2, varscan2
- OR2W3 | c.289T>A p.C97S | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV64458242; called by muse, mutect2, varscan2
- OR4C16 | c.659T>G p.L220W | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58942945, COSV58944670; called by muse, mutect2, varscan2
- OR4D6 | c.478G>A p.V160I | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV55661178; called by muse, mutect2, varscan2
- OR52A1 | c.261C>G p.F87L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV61093455; called by muse, mutect2
- OR5D14 | c.523G>C p.V175L | Missense Mutation (SNP) | VAF 33/179 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.141); catalogued as COSV100162410, COSV59459101; called by muse, mutect2, varscan2
- OR5M1 | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73202467; called by muse, mutect2, varscan2
- P2RY6 | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs193163379, COSV62937696; called by muse, mutect2, varscan2
- PCBP2 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs111807426, COSV63729469; called by muse, mutect2, varscan2
- PCDH18 | c.2743A>G p.M915V | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.914); catalogued as rs190379718, COSV100787548; called by muse, mutect2, varscan2
- PCDHB12 | c.1900G>T p.D634Y | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV53401798; called by muse, mutect2, varscan2
- PCNX1 | c.5375T>G p.L1792R | Missense Mutation (SNP) | VAF 51/85 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV53103567; called by muse, mutect2, varscan2
- PCYOX1L | c.1015G>T p.G339C | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51005126; called by muse, mutect2, varscan2
- PEG3 | c.2931C>A p.C977* | Nonsense Mutation (SNP) | VAF 12/113 reads (11%) | catalogued as COSV55650339; called by muse, mutect2, varscan2
- PF4 | c.143C>A p.S48Y | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1325290254, COSV56020820, COSV56021260; called by muse, varscan2
- PFAS | c.3943G>T p.D1315Y | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV58983955; called by muse, mutect2, varscan2
- PKHD1 | c.683G>T p.S228I | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as COSV61897616; called by muse, mutect2, varscan2
- PLCE1 | c.6003+1G>T p.X2001_splice | Splice Site (SNP) | VAF 23/89 reads (26%) | catalogued as COSV53375159; called by muse, mutect2, varscan2
- PPP1R21 | c.1707G>T p.L569F | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99682706; called by muse, mutect2, varscan2
- PRKCG | c.1764+1G>T p.X588_splice | Splice Site (SNP) | VAF 5/11 reads (45%) | catalogued as rs1406338491, COSV54734075, COSV54735488; called by muse, mutect2, varscan2
- PRKN | c.412G>C p.A138P | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.556); catalogued as COSV58285970; called by muse, mutect2, varscan2
- PRPS2 | c.817A>G p.N273D | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.311); catalogued as COSV66180382; called by muse, mutect2, varscan2
- PRR5 | c.183C>A p.D61E (on ENST00000336985 / NM_181333.4; = p.D52E on NM_015366.4) | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV50064178; called by muse, mutect2, varscan2
- PWWP3B | c.722C>A p.S241* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as COSV61798734, COSV61801985; called by muse, mutect2, varscan2
- RASSF8 | c.985C>T p.R329C | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as rs746967473, COSV51454323; called by muse, mutect2, varscan2
- REG1A | c.392G>T p.S131I | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0.112); catalogued as COSV52068898, COSV52071880; called by muse, mutect2, varscan2
- RLIM | c.1207C>A p.Q403K | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV60329508; called by muse, mutect2, varscan2
- RPAP1 | c.301C>G p.H101D | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58543026; called by muse, mutect2, varscan2
- RPRD2 | c.3209C>G p.S1070C | Missense Mutation (SNP) | VAF 4/97 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); catalogued as COSV64818922; called by muse, mutect2
- RYR2 | c.4148G>A p.R1383H | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs752124839, COSV63670842, COSV63680076; called by muse, mutect2, varscan2
- SCD | c.15G>T p.L5F | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.241); catalogued as COSV64853647; called by muse, mutect2, varscan2
- SEZ6 | c.2117G>A p.R706H | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758292539, COSV57977904, COSV57982312; called by muse, mutect2, varscan2
- SLC10A6 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.384); catalogued as rs201421765, COSV56721514; called by mutect2, varscan2
- SLC12A2 | c.2284A>T p.T762S | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV52477346; called by muse, mutect2, varscan2
- SLC16A1 | c.1106G>T p.W369L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0.411); catalogued as COSV63710532; called by muse, mutect2, varscan2
- SLC22A25 | c.25C>A p.Q9K | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as COSV60594710, COSV60599880; called by muse, mutect2, varscan2
- SLC30A8 | c.407G>T p.W136L | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV69977074; called by muse, mutect2, varscan2
- SLC35G1 | c.935G>T p.G312V (on ENST00000427197 / NM_001134658.3; = p.G311V on NM_153226.4) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV65055805; called by muse, mutect2, varscan2
- SLC35G5 | c.1000G>T p.G334W | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV55315697; called by muse, mutect2, varscan2
- SLIT2 | c.751C>G p.Q251E | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.643); catalogued as COSV56598713; called by muse, mutect2, varscan2
- SLITRK1 | c.1409T>A p.M470K | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV65677983; called by muse, mutect2, varscan2
- SNTG1 | c.278-2A>T p.X93_splice | Splice Site (SNP) | VAF 53/97 reads (55%) | catalogued as COSV52477430; called by muse, mutect2, varscan2
- SOWAHB | c.2009G>T p.G670V | Missense Mutation (SNP) | VAF 33/217 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57555708; called by muse, mutect2, varscan2
- SPATA13 | c.1792A>T p.R598W | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.375); catalogued as COSV57982083; called by muse, mutect2, varscan2
- SPHKAP | c.2315C>T p.S772F | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV60896965; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.335C>A p.T112N | Missense Mutation (SNP) | VAF 24/76 reads (32%) | PolyPhen probably damaging (0.985); catalogued as COSV100085692; called by muse, mutect2, varscan2
- STARD8 | c.1507C>A p.H503N | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.074); catalogued as COSV52933679, COSV99366056; called by muse, mutect2, varscan2
- SULT2A1 | c.807G>T p.L269F | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.473); catalogued as rs751509523, COSV55766710; called by muse, mutect2, varscan2
- SYT10 | c.350A>C p.K117T | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.013); catalogued as COSV57346359; called by muse, mutect2, varscan2
- TACC2 | c.7863G>T p.M2621I (on ENST00000334433; = p.M699I on NM_006997.4) | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV53291266; called by muse, mutect2, varscan2
- TAF4 | c.2137G>A p.V713M | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as rs771349625, COSV53339171; called by muse, mutect2, varscan2
- TEKT1 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as COSV58623572, COSV58625286; called by muse, mutect2, varscan2
- TENM2 | c.4297G>T p.E1433* (on ENST00000518659 / NM_001122679.2; = p.E1194* on NM_001080428.3) | Nonsense Mutation (SNP) | VAF 23/122 reads (19%) | catalogued as COSV69143903; called by muse, mutect2, varscan2
- TEP1 | c.2197G>T p.V733L | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV53001648; called by muse, mutect2, varscan2
- TM4SF18 | c.418A>T p.T140S | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0.029); catalogued as COSV56060211; called by muse, mutect2, varscan2
- TM9SF3 | c.805G>T p.G269* | Nonsense Mutation (SNP) | VAF 17/57 reads (30%) | catalogued as COSV64458850; called by muse, varscan2
- TNF | c.644C>A p.P215H | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV69304669, COSV69305458; called by muse, mutect2, varscan2
- TNR | c.1687G>C p.A563P | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.952); catalogued as COSV54907522, COSV54917514; called by muse, mutect2, varscan2
- TRAPPC9 | c.3399G>C p.W1133C | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66910955; called by muse, mutect2, varscan2
- TRIM3 | c.489G>T p.Q163H | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV61985960; called by muse, mutect2, varscan2
- TRPA1 | c.186G>T p.M62I | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV51576033; called by muse, mutect2, varscan2
- TSHB | c.124A>G p.I42V | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.162); catalogued as COSV56656262; called by muse, mutect2, varscan2
- TUBGCP2 | c.2667del p.P891Rfs*17 | Frame Shift Del (DEL) | VAF 5/16 reads (31%) | catalogued as rs770382851; called by mutect2, varscan2
- TULP4 | c.1358T>C p.V453A | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV65581811; called by muse, mutect2, varscan2
- UBR5 | c.3620G>T p.C1207F | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55279250, COSV55302231; called by muse, mutect2, varscan2
- USH2A | c.4697A>T p.Q1566L | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV56449605; called by muse, mutect2, varscan2
- USP26 | c.297C>A p.D99E | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as COSV63710013; called by muse, mutect2, varscan2
- VCAM1 | c.389G>A p.G130E | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV54122744; called by muse, mutect2, varscan2
- VPS13B | c.10589G>T p.R3530L | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs770999005, COSV62159960; called by muse, mutect2, varscan2
- VRK1 | c.623G>T p.G208V | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53711947; called by muse, mutect2, varscan2
- VSTM1 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58077135; called by muse, mutect2, varscan2
- WDR19 | c.3382G>A p.V1128I | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as COSV56470793; called by muse, mutect2, varscan2
- XKR9 | c.882G>T p.R294S | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.172); catalogued as COSV68773653; called by muse, mutect2, varscan2
- YLPM1 | c.5483G>T p.R1828L | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53122264; called by muse, mutect2, varscan2
- ZFP36L1 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60543926; called by muse, mutect2, varscan2
- ZFYVE28 | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.222); catalogued as rs530190181, COSV52118584; called by muse, mutect2, varscan2
- ZNF346 | c.383G>T p.R128I | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.806); catalogued as COSV56157482; called by muse, mutect2, varscan2
- ZNF460 | c.1547G>C p.S516T | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.024); catalogued as COSV64416606; called by muse, mutect2, varscan2
- ZNF536 | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 21/57 reads (37%) | catalogued as COSV62836043; called by muse, mutect2, varscan2
- ZNF551 | c.1736G>C p.R579T | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV56595469; called by muse, mutect2
- ZNF594 | c.2002G>T p.A668S | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV68386379; called by muse, mutect2, varscan2
- ZNF682 | c.559G>T p.G187C | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.91); catalogued as COSV100653373; called by muse, mutect2, varscan2
- ZNF721 | c.2142A>T p.K714N (on ENST00000338977; = p.K726N on NM_133474.4) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV59097806; called by muse, mutect2, varscan2
- ZSWIM5 | c.2303T>C p.L768S | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62737646; called by muse, mutect2, varscan2
- ZWINT | c.417G>T p.Q139H | Missense Mutation (SNP) | VAF 22/273 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV59185052; called by muse, mutect2
- ALDH1L1 | c.1964del p.G655Afs*5 | Frame Shift Del (DEL) | VAF 16/47 reads (34%) | called by mutect2, pindel, varscan2
- ATM | c.748_749del p.R250Sfs*3 | Frame Shift Del (DEL) | VAF 16/81 reads (20%) | called by mutect2, pindel, varscan2
- ATM | c.6017del p.L2006* | Frame Shift Del (DEL) | VAF 11/43 reads (26%) | called by mutect2, pindel, varscan2
- DNAJC16 | c.1788dup p.K597* | Frame Shift Ins (INS) | VAF 9/48 reads (19%) | called by mutect2, pindel, varscan2
- FCGBP | c.2918C>A p.T973K | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GARNL3 | c.594+2dup p.X198_splice | Splice Site (INS) | VAF 5/27 reads (19%) | called by mutect2, pindel
- GDF10 | c.899A>T p.D300V | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- HRC | c.412_423del p.G138_D141del | In Frame Del (DEL) | VAF 6/78 reads (8%) | called by mutect2, pindel
- IGLV3-32 | c.61G>T p.G21W | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- ITGA8 | c.813dup p.A272Cfs*31 | Frame Shift Ins (INS) | VAF 9/25 reads (36%) | called by mutect2, pindel, varscan2
- KIR3DL1 | c.283T>A p.C95S | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, varscan2
- KRT19 | c.765dup p.Y256Ifs*2 | Frame Shift Ins (INS) | VAF 11/101 reads (11%) | called by mutect2, varscan2
- MAP6 | c.906-2_906-1del p.X302_splice | Splice Site (DEL) | VAF 5/58 reads (9%) | called by mutect2, pindel
- NCAM2 | c.468del p.T157Lfs*10 | Frame Shift Del (DEL) | VAF 7/51 reads (14%) | called by mutect2, pindel, varscan2
- OPN4 | c.1131del p.H378Tfs*16 | Frame Shift Del (DEL) | VAF 4/31 reads (13%) | called by mutect2, pindel
- P3H4 | c.1057del p.R353Gfs*130 | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | called by mutect2, pindel, varscan2
- PCDH7 | c.2373dup p.R792Kfs*13 | Frame Shift Ins (INS) | VAF 9/52 reads (17%) | called by mutect2, pindel, varscan2
- PLCE1 | c.6747del p.I2250Ffs*27 | Frame Shift Del (DEL) | VAF 23/67 reads (34%) | called by mutect2, pindel, varscan2
- SPATA31A3 | c.2083G>T p.G695W | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.209); called by mutect2, varscan2
- STK11 | c.777del p.N259Kfs*28 | Frame Shift Del (DEL) | VAF 19/34 reads (56%) | called by mutect2, pindel, varscan2
- TESPA1 | c.1404_1426del p.D469Ffs*10 (on ENST00000316577 / NM_001098815.3; = p.D331Ffs*10 on NM_014796.2 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 17/220 reads (8%) | called by mutect2, pindel
- TMEM200A | c.1433del p.L478* | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- WDR61 | c.776_778del p.W259_D260delinsY | In Frame Del (DEL) | VAF 4/20 reads (20%) | called by mutect2, varscan2
- ZNF488 | c.601C>A p.L201I | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AFF2 | c.105A>G p.Q35= | Silent (SNP) | VAF 31/129 reads (24%) | catalogued as rs144497911, COSV60684355; called by muse, mutect2, varscan2
- AFF2 | c.306G>T p.V102= | Silent (SNP) | VAF 82/201 reads (41%) | catalogued as rs1557257806, COSV60664974, COSV60684373; called by muse, mutect2, varscan2
- AKR1C1 | c.699G>T p.P233= | Silent (SNP) | VAF 24/159 reads (15%) | catalogued as COSV66500088; called by muse, mutect2, varscan2
- ATP7B | c.3675G>A p.K1225= | Silent (SNP) | VAF 54/129 reads (42%) | catalogued as COSV54445225; called by muse, mutect2, varscan2
- CACNA1E | c.2139C>A p.T713= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV62434686; called by muse, mutect2, varscan2
- CACNA1E | c.6075G>C p.R2025= (on ENST00000367573 / NM_001205293.3; = p.R1982= on NM_000721.4) | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as COSV62434708; called by muse, mutect2, varscan2
- CACNA1S | c.3486C>A p.T1162= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as COSV62944641; called by muse, mutect2, varscan2
- CCND2 | c.132C>T p.F44= | Silent (SNP) | VAF 30/92 reads (33%) | catalogued as COSV54226024; called by muse, varscan2
- CDCA7 | c.819C>T p.C273= (on ENST00000347703 / NM_145810.3; = p.C352= on NM_031942.5) | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as COSV60721998; called by muse, mutect2, varscan2
- CHRM2 | c.21C>A p.S7= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV57786243; called by muse, mutect2, varscan2
- COLQ | c.706C>A p.R236= | Silent (SNP) | VAF 38/168 reads (23%) | catalogued as CM030023, COSV67524375, COSV67526240; called by muse, mutect2, varscan2
- CSMD3 | c.2268G>T p.G756= (on ENST00000297405 / NM_001363185.1; = p.G652= on NM_052900.3) | Silent (SNP) | VAF 78/127 reads (61%) | catalogued as rs769290304, COSV52107349; called by muse, mutect2, varscan2
- CYP26B1 | c.948C>A p.P316= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs1451524779, COSV50015310; called by muse, mutect2, varscan2
- CYP8B1 | c.174G>A p.K58= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV100296337; called by muse, mutect2, varscan2
- DBF4 | c.1014T>C p.F338= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs377042232; called by muse, mutect2
- ELP1 | c.2550A>G p.E850= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV65900335; called by muse, mutect2, varscan2
- EOMES | c.2034G>T p.G678= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as rs754539500, COSV55416120; called by muse, mutect2, varscan2
- FBXL4 | c.192T>C p.H64= | Silent (SNP) | VAF 28/103 reads (27%) | catalogued as COSV100014403; called by muse, varscan2
- FLG2 | c.2610C>T p.G870= | Silent (SNP) | VAF 73/537 reads (14%) | catalogued as COSV66174285; called by muse, mutect2, varscan2
- GALP | c.127C>T p.L43= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV62001364; called by muse, mutect2, varscan2
- GPR50 | c.357C>A p.I119= | Silent (SNP) | VAF 48/131 reads (37%) | catalogued as COSV54437635, COSV54443636; called by muse, mutect2, varscan2
- GSDMD | c.534G>A p.R178= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as rs1260882113, COSV52798465; called by muse, mutect2
- H2AW | c.306C>G p.T102= | Silent (SNP) | VAF 24/111 reads (22%) | catalogued as rs142593528, COSV64210272; called by muse, mutect2, varscan2
- HEATR6 | c.1158C>T p.F386= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as COSV51749586; called by muse, mutect2, varscan2
- HERC2 | c.5793G>A p.L1931= | Silent (SNP) | VAF 43/174 reads (25%) | catalogued as COSV55353528; called by muse, mutect2, varscan2
- HOXA10 | c.84T>C p.S28= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as rs774090455, COSV52227785; called by muse, mutect2, varscan2
- HTR1F | c.573C>T p.Y191= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs1330218552, COSV60391502; called by muse, mutect2, varscan2
- HTR2A | c.1311G>A p.K437= | Silent (SNP) | VAF 14/99 reads (14%) | catalogued as rs143205112; called by muse, mutect2, varscan2
- IGKV3-15 | c.198C>G p.L66= | Silent (SNP) | VAF 22/160 reads (14%) | catalogued as rs781708505; called by muse, mutect2, varscan2
- INHBC | c.705A>T p.R235= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV59006364; called by muse, mutect2, varscan2
- ITIH5 | c.444C>A p.P148= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV56900398, COSV56917083; called by muse, mutect2, varscan2
- KCNJ5 | c.609C>A p.S203= | Silent (SNP) | VAF 7/76 reads (9%) | catalogued as COSV57971948; called by muse, mutect2
- KREMEN1 | c.534C>T p.Y178= (on ENST00000407188; = p.Y180= on NM_032045.5) | Silent (SNP) | VAF 59/137 reads (43%) | catalogued as rs753289945, COSV59915106; called by muse, mutect2, varscan2
- LRRC18 | c.714C>G p.P238= | Silent (SNP) | VAF 52/154 reads (34%) | catalogued as COSV53286279; called by muse, mutect2, varscan2
- MYH7 | c.4030C>A p.R1344= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as rs727504352, CM122820, COSV62524882; called by muse, mutect2, varscan2
- MYT1L | c.1779C>G p.S593= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV101221556; called by muse, mutect2, varscan2
- NDRG4 | c.67C>A p.R23= (on ENST00000570248 / NM_001378344.1; = p.R55= on NM_020465.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 25/46 reads (54%) | catalogued as COSV50752258; called by muse, mutect2, varscan2
- NLRP3 | c.3072T>C p.P1024= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as COSV59511834; called by muse, mutect2, varscan2
- NLRP4 | c.2832C>A p.A944= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV56724909; called by muse, mutect2, varscan2
- NPHS2 | c.834G>C p.L278= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as COSV100858221; called by muse, mutect2
- OPRL1 | c.279G>T p.L93= | Silent (SNP) | VAF 50/152 reads (33%) | catalogued as COSV61093230; called by muse, mutect2, varscan2
- OR13C9 | c.648C>A p.I216= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV52243969; called by muse, mutect2, varscan2
- OR4C46 | c.717C>A p.V239= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV60221524; called by muse, mutect2
- OR4S1 | c.384G>T p.L128= | Silent (SNP) | VAF 28/100 reads (28%) | catalogued as rs1235213274, COSV60680437; called by muse, mutect2, varscan2
- OR52M1 | c.402T>C p.H134= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as rs1035426861, COSV64173081; called by muse, mutect2, varscan2
- OR5H6 | c.891A>T p.I297= (on ENST00000642105; = p.I281= on NM_001005479.2) | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as rs201216141, COSV67352190; called by muse, mutect2, varscan2
- PCDHA12 | c.438G>A p.A146= | Silent (SNP) | VAF 25/100 reads (25%) | catalogued as COSV56539357; called by muse, mutect2, varscan2
- PCDHB16 | c.165G>A p.G55= | Silent (SNP) | VAF 44/92 reads (48%) | catalogued as COSV53372490; called by muse, mutect2, varscan2
- PIGS | c.1593G>A p.V531= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as COSV52026924; called by muse, mutect2, varscan2
- PIGS | c.57C>T p.A19= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV52026931; called by muse, mutect2, varscan2
- PTPRK | c.1698G>T p.T566= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as rs748212883, COSV63908922; called by muse, mutect2, varscan2
- RPF1 | c.588T>A p.I196= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV65724843; called by muse, mutect2, varscan2
- RTL3 | c.183C>A p.P61= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV100329863, COSV58186235; called by muse, mutect2, varscan2
- SALL3 | c.2034G>T p.P678= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV73306709; called by muse, mutect2, varscan2
- SCN4A | c.4194G>A p.G1398= | Silent (SNP) | VAF 36/99 reads (36%) | catalogued as COSV71129531; called by muse, mutect2, varscan2
- SLC12A9 | c.303G>T p.G101= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as COSV51937698; called by muse, mutect2, varscan2
- SLC14A2 | c.102C>T p.S34= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV54915282; called by muse, mutect2, varscan2
- SLC34A2 | c.621G>A p.R207= | Silent (SNP) | VAF 39/51 reads (76%) | catalogued as COSV65943384; called by muse, mutect2, varscan2
- SLIT2 | c.3147C>T p.H1049= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs756872945, COSV56582524, COSV56598699; called by muse, mutect2, varscan2
- SMAD2 | c.558C>T p.I186= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as rs1240164482, COSV51066408; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.336C>A p.T112= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as rs1490050105, COSV100085696; called by muse, mutect2, varscan2
- SYNE1 | c.24690A>G p.E8230= (on ENST00000367255 / NM_182961.4; = p.E8159= on NM_033071.3) | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV55124770; called by muse, mutect2, varscan2
- SYT7 | c.885C>T p.A295= | Silent (SNP) | VAF 132/341 reads (39%) | catalogued as COSV55660100; called by muse, mutect2, varscan2
- TAS2R30 | c.588G>T p.L196= | Silent (SNP) | VAF 58/273 reads (21%) | catalogued as COSV67863349; called by muse, varscan2
- TCHHL1 | c.507A>T p.P169= | Silent (SNP) | VAF 38/100 reads (38%) | catalogued as COSV64287954; called by muse, mutect2, varscan2
- TMX3 | c.1158G>A p.L386= | Silent (SNP) | VAF 32/93 reads (34%) | catalogued as COSV55184539, COSV55188426; called by muse, mutect2, varscan2
- TRAPPC8 | c.2430A>C p.S810= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV51978385; called by muse, mutect2, varscan2
- TRPM1 | c.2805C>A p.I935= | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as COSV56643778, COSV99855277; called by muse, mutect2, varscan2
- TRPM1 | c.1569G>T p.P523= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as rs201426913, COSV56643800; called by muse, mutect2, varscan2
- TRPS1 | c.342A>G p.S114= (on ENST00000220888 / NM_001330599.2; = p.S127= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/109 reads (17%) | catalogued as COSV55265650; called by muse, mutect2, varscan2
- TSKS | c.1449C>A p.G483= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as rs773735944, COSV55880073; called by muse, mutect2, varscan2
- UGT8 | c.954A>G p.K318= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV60421595; called by muse, mutect2, varscan2
- USP48 | c.765A>G p.E255= | Silent (SNP) | VAF 8/95 reads (8%) | catalogued as rs769934960, COSV57615523; called by muse, mutect2
- VMP1 | c.1221_*3del | Silent (DEL) | VAF 6/56 reads (11%) | called by mutect2, pindel
- ZFHX4 | c.5748T>C p.F1916= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV51500498; called by muse, mutect2, varscan2
- ZNF568 | c.1518A>T p.V506= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as COSV61743286; called by muse, mutect2, varscan2
- ZNF713 | c.165A>C p.L55= (on ENST00000633730 / NM_001366796.2; = p.L68= on NM_182633.3) | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as COSV68888479; called by muse, mutect2, varscan2
- ZNRF4 | c.70C>T p.L24= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV55776669; called by mutect2, varscan2
- AP000769.5 | chr11:65497990 A>C | 5'Flank (SNP) | VAF 7/129 reads (5%) | called by muse, mutect2
- C11orf40 | n.296G>T | RNA (SNP) | VAF 22/93 reads (24%) | catalogued as COSV56891989; called by muse, mutect2, varscan2
- CTTN | c.*1141G>T | 3'UTR (SNP) | VAF 27/100 reads (27%) | catalogued as COSV100098494; called by muse, mutect2, varscan2
- FAM27E5 | n.265C>A | RNA (SNP) | VAF 20/73 reads (27%) | catalogued as rs371171005; called by muse, mutect2, varscan2
- PKD1L2 | n.1199G>T | RNA (SNP) | VAF 23/57 reads (40%) | called by muse, mutect2, varscan2
- SRPX2 | c.*2C>A | 3'UTR (SNP) | VAF 6/17 reads (35%) | catalogued as COSV99343452; called by muse, mutect2, varscan2
- TRNAU1AP | chr1:28578804 G>A | 3'Flank (SNP) | VAF 46/142 reads (32%) | called by muse, mutect2, varscan2
